Gene-level copy-number profile of specimen HCM-SANG-0304-C15-85A from HCMI case HCM-SANG-0304-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0304-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e7729948-2d31-44f4-bd98-51018c65ae93.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0304-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/60b7ff4c-4cae-4591-b70b-81b5670a8342

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,446; copy number 2: 33,941; copy number 3: 16,646; copy number 4: 5,187; copy number 5: 1,548; copy number 6: 15; copy number 8: 2; copy number 11: 1; copy number 18: 1; copy number 21: 91; copy number 26: 7; copy number 32: 1; copy number 39: 1; copy number 43: 1; copy number 61: 10; copy number 66: 6; copy number 73: 1; copy number 84: 4; copy number 92: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,691 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,612,006–151,699,091, 1 gene, copy number 5 (within-gene range 4–5): SNX27.
- chr1:151,700,058–151,909,637, 22 genes, copy number 5: CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2.
- chr1:156,806,243–156,881,850, 3 genes, copy number 5: SH2D2A, NTRK1, INSRR.
- chr1:157,709,086–157,725,020, 2 genes, copy number 5: AL356276.2, VDAC1P9.
- chr1:158,197,922–158,203,877, 1 gene, copy number 5: AL138899.1.
- chr1:158,514,785–158,515,925, 1 gene, copy number 5: OR10R1P.
- chr1:158,544,550–158,554,405, 1 gene, copy number 5: OR6Y1.
- chr1:158,578,919–158,700,652, 5 genes, copy number 5: OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2.
- chr1:159,466,321–159,536,007, 2 genes, copy number 5 (within-gene range 4–5): LINC02819, OR10J5.
- chr1:160,062,461–160,098,943, 3 genes, copy number 5 (within-gene range 4–5): AL121987.1, KCNJ9, IGSF8.
- chr1:160,537,073–160,571,458, 1 gene, copy number 5 (within-gene range 4–5): AL138930.1.
- chr1:163,468,496–163,468,605, 1 gene, copy number 5: RNA5SP62.
- chr5:32,522,758–32,604,079, 2 genes, copy number 5: AC074134.1, SUB1.
- chr5:35,429,064–41,510,628, 93 genes, copy number 11–21 (broad region; genes not listed).
- chr7:104,894,628–105,115,019, 7 genes, copy number 6–8 (within-gene range 4–8): LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3.
- chr8:126,325,454–128,564,679, 33 genes, copy number 26–92 (within-gene range 26–142): AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr12:220,621–389,320, 4 genes, copy number 5 (within-gene range 4–5): SLC6A13, AC007406.2, AC007406.4, KDM5A.
- chr12:459,939–2,697,950, 39 genes, copy number 5 (within-gene range 4–5): B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1.
- chr12:2,659,937–2,954,338, 20 genes, copy number 5: AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P.
- chr12:3,077,355–3,873,448, 18 genes, copy number 5 (within-gene range 3–5): TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1.
- chr14:18,333,726–18,650,966, 17 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr14:67,441,855–67,651,708, 10 genes, copy number 6 (within-gene range 3–6): MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4.
- chr15:22,145,939–22,152,897, 2 genes, copy number 5: AC010760.1, RPS8P10.
- chr17:39,603,536–39,696,797, 7 genes, copy number 5 (within-gene range 4–5): NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3.
- chr17:81,804,132–81,863,102, 6 genes, copy number 5: GCGR, MCRIP1, PPP1R27, P4HB, AC145207.3, AC145207.9.
- chr20:87,250–50,429,483, 1,082 genes, copy number 5 (broad region; genes not listed).
- chr20:50,794,894–64,327,972, 308 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
